Somatic mutation profile of tumor specimen TARGET-50-PAKPDF-01A (aliquot TARGET-50-PAKPDF-01A-01D) from TARGET case TARGET-50-PAKPDF, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: female; Vital status: Dead; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 5.2 years (1,912 days).
Specimen TARGET-50-PAKPDF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8fb0f18d-7ca8-49e8-9a20-5ff4c6760d0a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PAKPDF-10A (Blood Derived Normal), aliquot TARGET-50-PAKPDF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad322ab4-e788-49f3-92ea-b402b19cc825

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- METTL27 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV52897572; called by muse, mutect2
- RAB11FIP1 | c.407A>G p.D136G | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as COSV54759804; called by muse, mutect2, varscan2
- KRTAP10-11 | c.277T>C p.S93P | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.024); called by muse, mutect2
- PIP5K1B | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.411); called by muse, mutect2
- TP53 | c.1021_1027del p.F341Sfs*2 | Frame Shift Del (DEL) | VAF 32/34 reads (94%) | called by mutect2, pindel, varscan2
- ZNF282 | c.1681C>A p.L561I | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
